Somatic mutation profile of tumor specimen TCGA-X7-A8M6-01A (aliquot TCGA-X7-A8M6-01A-11D-A423-09) from TCGA case TCGA-X7-A8M6, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B2, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 43.1 years (15,749 days).
Specimen TCGA-X7-A8M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4faac126-f6f4-4a9c-861c-a7718760090b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8M6-10A (Blood Derived Normal), aliquot TCGA-X7-A8M6-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7f10f0d-b642-4032-9412-5aecc652d161

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC1 | c.3137G>A p.R1046H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs761512468; called by muse, mutect2
- DCST1 | c.757A>G p.N253D | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- MARCHF10 | c.2317G>C p.E773Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ADGRB3 | c.1950C>T p.S650= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
